Somatic mutation profile of tumor specimen MP2PRT-PAPZUE-TMP1-A (aliquot MP2PRT-PAPZUE-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZUE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,444 days).
Specimen MP2PRT-PAPZUE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccecaf3-60a2-4d21-911f-9bd7eff232aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZUE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZUE-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/979bddd7-a2b6-403c-a2f9-9b2b238e27b7

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 43/299 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.4408C>T p.R1470C | Missense Mutation (SNP) | VAF 16/536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1328011806, COSV62409697; called by muse, mutect2
- DAB2IP | c.2305G>A p.V769I (on ENST00000408936; = p.V741I on NM_032552.3) | Missense Mutation (SNP) | VAF 221/506 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs761619061, COSV52265360; called by muse, mutect2, varscan2
- KCNG2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 75/945 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs1229743824; called by muse, mutect2
- LRRC9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs749979554; called by muse, mutect2, varscan2
- MAFA | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs886693089; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD3 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs752124291; called by muse, mutect2, varscan2
- PRDM2 | c.4209_4213delinsCC p.N1404_F1405delinsL | In Frame Del (DEL) | VAF 114/293 reads (39%) | called by pindel, varscan2*
- ANK3 | c.7248G>A p.V2416= | Silent (SNP) | VAF 87/422 reads (21%) | called by muse, mutect2, varscan2
- CBY2 | c.822G>A p.T274= | Silent (SNP) | VAF 114/331 reads (34%) | called by muse, mutect2, varscan2
- KRT9 | c.60C>A p.G20= | Silent (SNP) | VAF 46/369 reads (12%) | catalogued as rs765454147, COSV55851732; called by muse, mutect2, varscan2
- FN1 | c.3797-1151C>T | Intron (SNP) | VAF 33/264 reads (13%) | catalogued as rs760128957, COSV100115653; called by muse, mutect2, varscan2
